Somatic mutation profile of tumor specimen 0DQ2ND from CCDI case PBCEKW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 9.7 years (3,555 days).
Specimen 0DQ2ND: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6aceeb9c-a13e-47eb-af3b-e9101b56c31b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ2P0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e379a9e-b46b-4472-bd3f-77b337b153cf

The open-access MAF lists 36 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 8, Intron 3, 3'UTR 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.3727C>T p.R1243W | Missense Mutation (SNP) | VAF 240/445 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60786131, COSV60797427; called by muse, mutect2, varscan2
- CPXM2 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 294/616 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs759082507, COSV53859579; called by muse, mutect2, varscan2
- DNAH10 | c.3178C>A p.L1060I (on ENST00000409039; = p.L999I on NM_207437.3) | Missense Mutation (SNP) | VAF 247/833 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); catalogued as COSV68991224; called by muse, mutect2, varscan2
- FRS2 | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 37/540 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs112443855, COSV54722796; called by muse, mutect2
- ITGA3 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 88/1265 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs757264679; called by muse, mutect2
- MET | c.2465T>G p.M822R | Missense Mutation (SNP) | VAF 461/1220 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV59260570; called by muse, mutect2, varscan2
- MYOM3 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 71/508 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs527972499, COSV58393510; called by muse, mutect2, varscan2
- OR9A2 | c.898G>T p.G300W | Missense Mutation (SNP) | VAF 403/728 reads (55%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.711); catalogued as COSV63306499; called by muse, mutect2, varscan2
- PENK | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 58/387 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767796107, COSV59240443; called by muse, mutect2, varscan2
- PLXNA4 | c.1601A>G p.N534S | Missense Mutation (SNP) | VAF 141/438 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs1217574380; called by muse, mutect2, varscan2
- SAMD4B | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs767556722; called by muse, mutect2
- STAG2 | c.3034C>T p.R1012* | Nonsense Mutation (SNP) | VAF 22/651 reads (3%) | catalogued as COSV54350913; called by muse, mutect2
- TBX4 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 68/940 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as rs200962877; called by muse, mutect2
- WDR7 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 69/609 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as rs141522942; called by muse, mutect2, varscan2
- YBX2 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 198/372 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1404773914; called by muse, mutect2, varscan2
- BMS1 | c.3767A>G p.K1256R | Missense Mutation (SNP) | VAF 302/635 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FAM90A1 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 66/788 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); called by muse, mutect2
- HNRNPK | c.213+1G>C p.X71_splice | Splice Site (SNP) | VAF 79/576 reads (14%) | called by muse, mutect2, varscan2
- MYO10 | c.5670G>T p.R1890S | Missense Mutation (SNP) | VAF 25/687 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.835); called by muse, mutect2
- OR51E1 | c.290T>G p.F97C | Missense Mutation (SNP) | VAF 212/254 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRTG | c.2377T>A p.F793I | Missense Mutation (SNP) | VAF 114/1313 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); called by muse, mutect2
- RPH3A | c.377G>A p.C126Y (on ENST00000389385 / NM_001143854.2; = p.C122Y on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 220/769 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- TBC1D26 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 172/514 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- TPGS1 | c.123G>C p.Q41H | Missense Mutation (SNP) | VAF 80/276 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FAM187A | c.375C>T p.C125= | Silent (SNP) | VAF 58/796 reads (7%) | catalogued as rs376556091; called by muse, mutect2
- GAL3ST3 | c.1233C>T p.P411= | Silent (SNP) | VAF 12/414 reads (3%) | catalogued as rs1333044029; called by muse, mutect2
- GDF6 | c.756C>G p.P252= | Silent (SNP) | VAF 104/177 reads (59%) | called by muse, mutect2, varscan2
- LRBA | c.7638G>C p.A2546= | Silent (SNP) | VAF 461/935 reads (49%) | called by muse, mutect2, varscan2
- LRRC8E | c.126C>T p.G42= | Silent (SNP) | VAF 154/275 reads (56%) | called by muse, mutect2, varscan2
- MMP28 | c.1023T>C p.I341= | Silent (SNP) | VAF 543/900 reads (60%) | called by muse, mutect2, varscan2
- MTHFD2L | c.6G>A p.T2= | Silent (SNP) | VAF 12/402 reads (3%) | catalogued as rs1156739078; called by muse, mutect2
- SKI | c.876G>C p.T292= | Silent (SNP) | VAF 50/411 reads (12%) | catalogued as rs746196973; called by muse, mutect2, varscan2
- ANXA2 | c.49-72A>G | Intron (SNP) | VAF 34/83 reads (41%) | catalogued as rs554090145; called by muse, mutect2, varscan2
- FLT4 | c.2647+52T>C | Intron (SNP) | VAF 75/142 reads (53%) | called by muse, mutect2, varscan2
- GSTA5 | c.*60A>T | 3'UTR (SNP) | VAF 136/278 reads (49%) | catalogued as rs1274081809; called by muse, mutect2, varscan2
- LMLN2 | c.1477-17T>C | Intron (SNP) | VAF 26/225 reads (12%) | called by muse, mutect2, varscan2
